Surgical pathology report (de-identified scan), TCGA case TCGA-06-0187, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0187-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-0187

Surgical Pathology Report

CLINICAL HISTORY

has right parietal brain tumor, intra axial.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, right parietal, biopsy
B: Right parietal Brain, resection

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right parietal, excision: Glioblastoma.
See comment.

COMMENT

The specimen is portions of cerebrum diffusely infiltrated and extensively effaced by an astrocytic neoplastic proliferation with nuclear anaplasia, mitotic figures, prominent microvascular cellular proliferation, and zones of necrosis. There are several multinucleated cells. Special stains to better characterize the neoplasm are being requested and will be reported as an addendum.

PROCEDURES/ADDENDA

Immunohistology

Date Ordered: Date Reported:

Interpretation

MIB-1 PROLIFERATION INDEX: 21%
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates glial fibrillogenesis by the neoplastic cells. The neuronal markers fail to demonstrate a neoplastic neuronal component. Only about 1% of tumor cells over express the p53 protein. With the MIB-1 there is a proliferation index of about 21% in the more active areas.

[page 2 of 3]
[REDACTED]

Comment: These immuno results support a diagnosis of high histological grade glioma without a neuronal component.

TCGA-06-0187

[REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Submitted, paraffin curls on block B1.

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

Brain right parietal, touch prep and smears: Glioma, high histological grade.

[REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
Received fresh, thre fragments, 1.2 cm. in aggregate. Semi firm, tannish-grey, glassy. In total, A1-A3.

B.
SPECIMEN: Right parietal brain tumor.
FIXATIVE: Formalin.
GENERAL: A 2.0 x 1.5 x 0.7 cm or less, 1.09 gm, few irregularly shaped pale red-tan to gray-white tissue fragments.
SECTIONS: A1 - all submitted.

[REDACTED]

[page 3 of 3]
ICD-9(s):
191.9 191.9

TCGA-06-0187

Histo Data

Part A: Brain, right parietal, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt		1		
H/E x 1		1		

Part B: Right parietal Brain, resection

Taken:	Received:	Block	Ordered	Comment
Stain/cnt		1		
CD34-DA x 1		1		
mGFAP-DA x 1		1		
H/E x 1		1		
MGMT x 1		1		
MIB1-DA x 1		1		
NF2F11 x 1		1		
NSE-DA x 1		1		
P53DO7 x 1		1		

*** End of Report ***

Source: NCI Genomic Data Commons file 606ff9bd-d32b-4b1c-aede-a912f60d66a3 (TCGA-06-0187.17F164B8-9DC6-48F0-830B-60FC0EFA83B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).